Surgical pathology report (de-identified scan), TCGA case TCGA-68-A59I, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-68-A59I-01A (Primary Tumor).

[page 1 of 5]
Diagnostic Discrepancy		✓

SURGICAL PATHOLOGY REPORT

Patient Age/Sex / F

SPECIMEN SUBMITTED:

Part A: LEFT LUNG

Part B: LEFT RIB

Part C: 7R

Part D: 11L

Part E: 10L

ICD-O-3

Carcinoma, Squamous Cell NOS

Site: Lung, lower lobe
867013
C34.3
pT1 1/1/13

Final Diagnosis

1. Left lung, pneumonectomy (A) - Invasive moderately differentiated squamous cell carcinoma.
- Three (3) of fifteen (15) lymph nodes positive for tumor (3/15).
2. Left rib, partial excision (B) - Grossly unremarkable rib (gross diagnosis only).
3. Lymph node, 7R, excision (C) Non-diagnostic. (See general comment).
4. Lymph node, 11L, excision (D) One (1) node with metastatic squamous cell carcinoma. (1/1).
5. Lymph nodes, 10L, excision (E) Two (2) of three (3) lymph nodes with metastatic squamous cell carcinoma (2/3).

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

LUNG SYNOPTIC REPORT

SPECIMEN: Lung

PROCEDURE: Pneumectomy

SPECIMEN INTEGRITY: Disrupted

SPECIMEN LATERALITY: Left

TUMOR SITE: Lower lobe

TUMOR SIZE: 8.0 x 7.0 x 6.0 cm.

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Squamous cell carcinoma

HISTOLOGIC GRADE: G2 moderately differentiated

VISCERAL PLEURAL INVASION: Not identified.

TUMOR EXTENSION: Tumor involves main bronchus 2 cm or more distal to carina

MARGINS:

- Bronchial margin: Uninvolved by invasive carcinoma and carcinoma in situ.
- Vascular Margin: Uninvolved by invasive carcinoma
- Parenchymal margin: Not applicable.
- Parietal pleural margin: Uninvolved by invasive carcinoma.
- Chest wall margin: Not applicable.
- Other attached tissue margin: Pericardial margin uninvolved by invasive carcinoma. Diaphragmatic margin uninvolved by invasive carcinoma
- Distance of invasive carcinoma from closest margin: 0.2 cm (mediastinal margin).
- TREATMENT EFFECT: Not applicable.
- TUMOR ASSOCIATED ATELECTASIS OR OBSTRUCTIVE PNEUMONITIS: Involves entire lung.
- LYMPH-VASCULAR INVASION: Present.
- LYMPH NODES: Extranodal extension not identified.

PATHOLOGIC STAGING: Stage IIIA

pT3

pN1

Number of lymph nodes examined: 19 (not including part C)

Number of lymph nodes involved: 6 (not including part C).

pM Not applicable.

Additional pathologic findings not identified.

Ancillary studies: Immunohistochemistry for p63 and TTF1 were performed on block A6 during the interpretation of this case and support the diagnosis of squamous cell carcinoma.

General comment: Tissue from the Specimen labeled 7R (Part C) was lost in processing in the Department of Anatomic Pathology and therefore is non-diagnostic. Overall pathologic staging of the specimen is not affected.

Intraoperative Diagnosis:

- A. Lung, left, pneumectomy (FS) - Bronchial margin, negative for neoplasm

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis:

H/O LUNG CANCER

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received in formalin is a specimen labeled "left lung". The specimen consists of a lung measuring 15 x 10 x 7.5 cm, tightly adhered pericardium measuring 10 x 8.5 x 0.5 cm and diaphragm measuring 4.5 x 2 x 0.2 cm. The specimen weighs 606 grams. The bronchial remnant measures 2.4 cm in length and 1.4 cm in diameter. The pericardium is inked green, the diaphragm margin is inked black, the mediastinal soft tissue margin and perihilar pleural surface is inked blue. The pleura is incomplete on the lateral aspect of the lung on both the upper and lower lobes (orange ink). The diaphragmatic surface of the lung is also incomplete with an open defect showing a visibly necrotic cavity within the lower lobe of the lung. No areas of puckering are present along the pleural surface. The specimen is sectioned in a transverse plane to reveal a firm, gray-white mass with central necrosis measuring 8 x 7 x 6 cm. The necrosis is more prominent in the most inferior aspect of the lung. The greatest dimension of the mass is in the cranial caudal plane. The mass is present from the hilar region and extends inferior through the lower lobe to the diaphragmatic aspect. The lung parenchyma adjacent to the mass is soft and tan-orange. The upper and lower lobes are firmly adhered at the oblique fissure in the area of the mass showing possible involvement in the upper lobe (section A14). The mass does involve the bronchus and extending within 1.5 cm from the bronchial margin. The mass grossly abuts the diaphragm margin (black inked), the medial pleural surface at the level surrounding the hilum (blue inked) and the lateral pleural defect (inked orange). The mass comes within 0.3 cm of the mediastinal tissue margin (blue inked) and within 0.5 cm of the pericardial margin (green inked). The vessels at the hilar level appear to be grossly involved. Mucous plugs are identified diffusely throughout the bronchi. The mucous plugs are prominent within the posterior aspect of the upper and lower lobe bronchioles ranging in size from 0.1 to 0.2 cm. The upper lobe lung parenchyma appears grossly unremarkable and is smooth, red and spongy. No intraparenchymal lymph nodes are identified. Peribronchial lymph nodes are identified and range in size from 0.3 to 1.3 cm. Perihilar lymph nodes are identified and range in size from 0.9 to 1.6 cm. Representative sections are submitted as follows: A2 - vascular shave margin; A3 -A5 - mass in relationship to diaphragm; A6 - mass in relationship to mediastinal soft tissue margin; A7 and A8 - mass in relationship to pericardial margin; A9 - mass in relationship to bronchus and pleura; A10 through A13 - mass in relationship to pleural margin; A14 - mass at lung fissure; A15 - mass in relationship to hilar vasculature; A16 - mass in relationship to lateral pleural defect; A17 and A18 - additional sections of mass non-marginal; A19 and A20 - sections of upper lobe posterior aspect with mucus plugs; A21 - section of upper lobe anterior aspect; A22 - section of upper lobe middle aspect; A23 - section of apex; A24 - perihilar lymph nodes; A25- A26 - peribronchial lymph nodes.

B. Received fresh labeled "L rib" is one fragment of rib measuring 18 cm x 1.7 x 0.6 cm. No sections are submitted. Gross diagnosis only.

C. Received fresh on Telfa gauze labeled "7R" is an irregular-shaped segment of red-gray soft tissue measuring 1.8 x 1.0 x 0.4 cm. The specimen is totally submitted in formalin in one cassette.

D. Received fresh on Telfa gauze labeled "11L" is an irregular-shaped segment of red-gray soft tissue measuring 2.1 x 1.3 x 0.6 cm. The specimen is totally submitted in formalin in one cassette.

E. Received fresh on Telfa gauze labeled "10L" are multiple irregular-shaped segments of red-gray soft

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Gross Description:

tissue aggregating to 1.8 x 1.1 x 0.4 cm. The specimen is totally submitted in formalin in one cassette.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 21584b39-d586-48c1-ad68-7be22f06689f (TCGA-68-A59I.B0897B1D-F870-489E-9D9C-C670982BB3E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).